Somatic mutation profile of tumor specimen C3N-01530-01 (aliquot CPT0096150009) from CPTAC case C3N-01530, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 83.5 years (30,485 days).
Specimen C3N-01530-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc6536a0-34dd-455c-acfa-398d86b841c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01530-71 (Blood Derived Normal), aliquot CPT0096190002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d0f9128-d137-4c89-9fde-08b398fee6af

The open-access MAF lists 364 somatic variants for this specimen: 239 protein-altering or splice-affecting, 117 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 228, Silent 117, Nonsense Mutation 5, Intron 5, Splice Region 2, Frame Shift Del 2, In Frame Del 2, 5'UTR 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNH2 | c.2582A>G p.N861S | Missense Mutation (SNP) | VAF 33/296 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs121912513, CM002314; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.313_318del p.P105_A106del | In Frame Del (DEL) | VAF 60/266 reads (23%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ACAN | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 122/432 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs761696605, COSV100718653; called by muse, mutect2, varscan2
- ACE | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 66/328 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.116); catalogued as rs770430455; called by muse, mutect2, varscan2
- ADCY10 | c.1952C>T p.S651L | Missense Mutation (SNP) | VAF 76/393 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs757907800, COSV100896881; called by muse, mutect2, varscan2
- ADD2 | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 113/390 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs149050833; called by muse, mutect2, varscan2
- ANO3 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 59/241 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs754306957, COSV56785250, COSV56806565; called by muse, mutect2, varscan2
- ATXN1L | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 103/387 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs1414438566; called by muse, mutect2, varscan2
- BSN | c.9823C>T p.L3275F | Missense Mutation (SNP) | VAF 59/374 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.212); catalogued as rs1393789674; called by muse, mutect2, varscan2
- CADPS2 | c.637G>C p.G213R | Missense Mutation (SNP) | VAF 33/433 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1334536052, COSV57360979; called by muse, mutect2
- CATSPERB | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 57/412 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56421965; called by muse, mutect2, varscan2
- CCDC181 | c.1430C>T p.T477I (on ENST00000367806 / NM_001300969.1; = p.T476I on NM_021179.2) | Missense Mutation (SNP) | VAF 68/398 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs201318451; called by muse, mutect2, varscan2
- CD3D | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.44); catalogued as rs758839719, COSV52674885; called by muse, mutect2, varscan2
- CDH12 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.052); catalogued as COSV66389249, COSV66451901; called by muse, mutect2
- CFAP47 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 116/225 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV52884843, COSV52891359; called by muse, mutect2, varscan2
- CFAP61 | c.2957G>A p.R986K | Missense Mutation (SNP) | VAF 148/477 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV55624591; called by muse, mutect2, varscan2
- CHRNA4 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 208/665 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1264777378; called by muse, mutect2, varscan2
- COL2A1 | c.2486C>T p.P829L | Missense Mutation (SNP) | VAF 60/427 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs375253238; called by muse, mutect2, varscan2
- COL4A6 | c.2509G>A p.G837S | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs988697230; called by muse, mutect2, varscan2
- CPN2 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 79/429 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs751515015, COSV60470004; called by muse, mutect2, varscan2
- CPS1 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 79/279 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99243809; called by muse, mutect2, varscan2
- CSMD1 | c.2110C>T p.P704S (on ENST00000520002; = p.P703S on NM_033225.6) | Missense Mutation (SNP) | VAF 114/363 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59337012; called by muse, mutect2, varscan2
- CST11 | c.260T>G p.V87G | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100983564; called by muse, mutect2
- CTSO | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 88/431 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.862); catalogued as rs761352356; called by muse, mutect2, varscan2
- CYP4F11 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 71/411 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as rs752351878, COSV56126350; called by muse, mutect2, varscan2
- DDX41 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 70/248 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs1450576850; called by muse, mutect2, varscan2
- DDX60 | c.4489C>T p.P1497S | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV101190771; called by muse, mutect2, varscan2
- EEF2 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 83/420 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV58579245; called by muse, mutect2, varscan2
- EPHA7 | c.320G>T p.R107M | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV65169881; called by muse, mutect2
- ESM1 | c.354G>C p.Q118H | Missense Mutation (SNP) | VAF 33/433 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as COSV67319014; called by muse, mutect2
- ETS2 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 83/366 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV62872332; called by muse, mutect2, varscan2
- EZH1 | c.1925A>T p.Y642F | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV70550424; called by muse, varscan2
- F9 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as CM940526, COSV54379223; called by muse, mutect2, varscan2
- FGD2 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 73/342 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs763683329, COSV51464814; called by muse, mutect2, varscan2
- FLYWCH1 | c.908C>T p.T303I (on ENST00000253928 / NM_001308068.2; = p.T302I on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/419 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs372022354, COSV54144190; called by muse, mutect2, varscan2
- FMO3 | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 62/392 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63006836; called by muse, mutect2, varscan2
- GALNTL6 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 28/386 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs368909538; called by muse, mutect2
- GLYATL3 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 76/376 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV64591967; called by muse, mutect2, varscan2
- GRM3 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 75/376 reads (20%) | SIFT tolerated (0.88); PolyPhen benign (0.155); catalogued as COSV64471988; called by muse, mutect2, varscan2
- GSTA3 | c.530A>G p.N177S | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1241783260; called by muse, mutect2, varscan2
- HDAC9 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 97/395 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777828245, COSV67770295; called by muse, mutect2, varscan2
- HPS3 | c.2015C>T p.S672L | Missense Mutation (SNP) | VAF 65/325 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as rs1195256211; called by muse, mutect2, varscan2
- HRG | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 64/335 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs767043667, COSV99214688; called by muse, mutect2, varscan2
- HSPB8 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 114/377 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.362); catalogued as rs1375501110; called by muse, mutect2, varscan2
- IGF2BP3 | c.19G>C p.G7R | Missense Mutation (SNP) | VAF 75/283 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs267601464, COSV99325983; called by muse, mutect2, varscan2
- ITGAM | c.1993C>T p.R665W (on ENST00000648685 / NM_001145808.2; = p.R664W on NM_000632.4) | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372150584; called by muse, mutect2, varscan2
- KCNC4 | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 39/588 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV100873667; called by muse, mutect2
- KCNH5 | c.1823G>A p.G608E | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1265545832, COSV59759656; called by muse, mutect2, varscan2
- KCNK16 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 74/298 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768612699; called by muse, mutect2, varscan2
- LAMP1 | c.302C>T p.T101I | Missense Mutation (SNP) | VAF 87/494 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as rs971601002; called by muse, mutect2, varscan2
- LGR5 | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 30/414 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.953); catalogued as rs1433966113; called by muse, mutect2
- MAGEC3 | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 183/363 reads (50%) | catalogued as rs1210749310, COSV53575606; called by muse, mutect2, varscan2
- MALRD1 | c.3850G>A p.D1284N | Missense Mutation (SNP) | VAF 58/243 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1339042444; called by muse, mutect2, varscan2
- MAP3K11 | c.1796C>T p.P599L | Missense Mutation (SNP) | VAF 72/340 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as rs778810390, COSV100482751; called by muse, mutect2, varscan2
- MOSPD3 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 24/382 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs771584695, COSV56158679; called by muse, mutect2
- MS4A14 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 89/367 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV55735090, COSV55736401; called by muse, mutect2, varscan2
- MUC16 | c.5621G>A p.R1874K | Missense Mutation (SNP) | VAF 83/372 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.567); catalogued as rs369596151; called by muse, mutect2
- MUC16 | c.4430C>T p.S1477L | Missense Mutation (SNP) | VAF 109/371 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs745903249, COSV67501354; called by muse, mutect2, varscan2
- MVP | c.1336C>T p.L446F | Missense Mutation (SNP) | VAF 99/470 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV100651581, COSV62423638; called by muse, mutect2, varscan2
- NALCN | c.2728C>T p.R910* | Nonsense Mutation (SNP) | VAF 67/367 reads (18%) | catalogued as rs749065348, COSV51947194; called by muse, mutect2, varscan2
- NAV1 | c.3250C>T p.R1084W | Missense Mutation (SNP) | VAF 49/272 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs766624611, COSV55219389; called by muse, varscan2
- NFKBIE | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 119/547 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); catalogued as COSV51487728; called by muse, mutect2, varscan2
- NLRP4 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 74/404 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as COSV100016338; called by muse, mutect2, varscan2
- NOVA1 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 62/425 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57473034, COSV99948497; called by muse, mutect2, varscan2
- NR1D2 | c.1684C>T p.R562* | Nonsense Mutation (SNP) | VAF 94/326 reads (29%) | catalogued as rs1352385412, COSV56991577, COSV56992263; called by muse, mutect2, varscan2
- NUP155 | c.1157C>T p.T386M (on ENST00000231498 / NM_153485.3; = p.T327M on NM_004298.4) | Missense Mutation (SNP) | VAF 44/355 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs368991435; called by muse, mutect2, varscan2
- OR2T12 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 105/370 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100527833; called by muse, mutect2, varscan2
- OR2T2 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 32/1285 reads (2%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs1024191710, COSV61617691, COSV61617841; called by muse, mutect2
- OR2W1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 67/306 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs896592244, COSV65851468; called by muse, mutect2, varscan2
- OR4C15 | c.523C>T p.R175C (on ENST00000314644; = p.R121C on NM_001001920.2) | Missense Mutation (SNP) | VAF 116/484 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as rs267602969, COSV58951118, COSV58951281; called by muse, mutect2, varscan2
- PABPC1L | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 137/693 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53842156; called by muse, mutect2, varscan2
- PARM1 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 87/491 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1389763301, COSV56650901; called by muse, mutect2, varscan2
- PAX8 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 30/379 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs1044700320; called by muse, mutect2
- PCED1B | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 150/485 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV71394934; called by muse, mutect2, varscan2
- PDHX | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 102/424 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs147958676; called by muse, mutect2, varscan2
- PKD1L3 | c.4592G>A p.R1531Q | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs188435489; called by muse, mutect2, varscan2
- PLEKHH3 | c.1877C>T p.T626M | Missense Mutation (SNP) | VAF 101/389 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs775050583, COSV52217189; called by muse, mutect2, varscan2
- PTPRB | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 125/454 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.908); catalogued as COSV54241402; called by muse, mutect2, varscan2
- PTPRT | c.3412G>A p.D1138N | Missense Mutation (SNP) | VAF 117/376 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746243026, COSV61995239; called by muse, mutect2, varscan2
- RAB40C | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 113/561 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.959); catalogued as COSV50193863; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 143/537 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54573800; called by muse, mutect2, varscan2
- RIMS2 | c.1532C>T p.S511L (on ENST00000666250 / NM_001348490.2; = p.S319L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/779 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51650842; called by muse, mutect2
- RIN3 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 100/310 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.323); catalogued as rs1447891893; called by muse, mutect2, varscan2
- RIOK1 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV53571506; called by muse, mutect2, varscan2
- RNF213 | c.691C>T p.H231Y | Missense Mutation (SNP) | VAF 132/517 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as rs371554385; called by muse, mutect2, varscan2
- RUNDC3A | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 107/350 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV56588308; called by muse, mutect2, varscan2
- SASH1 | c.2809C>T p.P937S | Missense Mutation (SNP) | VAF 25/428 reads (6%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs886359906; called by muse, mutect2
- SH3PXD2A | c.2942C>T p.S981L (on ENST00000369774 / NM_001365079.1; = p.S953L on NM_014631.2) | Missense Mutation (SNP) | VAF 117/399 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1203701944, COSV100280566; called by muse, mutect2, varscan2
- SHISA9 | c.923C>T p.T308I | Missense Mutation (SNP) | VAF 56/342 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs879741742; called by muse, mutect2, varscan2
- SI | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.123); catalogued as COSV52269504; called by muse, mutect2, varscan2
- SLAMF6 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 76/404 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.331); catalogued as rs1233386461; called by muse, mutect2, varscan2
- SLC22A13 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 37/291 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV61292300; called by muse, mutect2, varscan2
- SLC25A18 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 81/337 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53659323; called by muse, mutect2, varscan2
- SLC26A7 | c.1304A>T p.K435I | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV52590094; called by muse, mutect2, varscan2
- SLC6A12 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.114); catalogued as COSV100674975; called by muse, mutect2, varscan2
- SLITRK1 | c.1050C>G p.I350M | Missense Mutation (SNP) | VAF 38/634 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.827); catalogued as COSV101000048; called by muse, mutect2
- SOX8 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 140/614 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1473172780, COSV53509502; called by muse, mutect2, varscan2
- SUGP1 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 62/325 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs758652218; called by muse, mutect2, varscan2
- SYNJ2 | c.3655G>A p.E1219K | Missense Mutation (SNP) | VAF 131/448 reads (29%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.012); catalogued as rs771437341; called by muse, mutect2, varscan2
- TACC2 | c.2881G>T p.V961F | Missense Mutation (SNP) | VAF 81/314 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.233); catalogued as rs376454944; called by muse, mutect2, varscan2
- TACC2 | c.6224C>T p.S2075F (on ENST00000334433; = p.S153F on NM_006997.4) | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53279593; called by muse, mutect2, varscan2
- TBC1D17 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 128/523 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); catalogued as rs780871278; called by muse, mutect2, varscan2
- TIMELESS | c.1655G>A p.S552N | Missense Mutation (SNP) | VAF 123/505 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.365); catalogued as rs376768006; called by muse, mutect2, varscan2
- TLE3 | c.1699C>T p.R567C | Missense Mutation (SNP) | VAF 115/395 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); catalogued as rs776248356; called by muse, mutect2, varscan2
- TMC7 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 64/277 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.821); catalogued as COSV100432511; called by muse, mutect2, varscan2
- TMC7 | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 88/445 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.844); catalogued as COSV58582503; called by muse, mutect2, varscan2
- TP53I11 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 63/294 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as rs1409410956; called by muse, mutect2, varscan2
- TPO | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 163/555 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61111439; called by muse, mutect2, varscan2
- TRMT44 | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 83/485 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV67664327; called by muse, mutect2, varscan2
- TRPM8 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 80/291 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.214); catalogued as rs201840075, COSV100224354; called by muse, mutect2, varscan2
- TTC9C | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs753620423, COSV53665911; called by muse, mutect2, varscan2
- TTLL9 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 70/294 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as rs564856380, COSV60591833; called by muse, mutect2, varscan2
- USP17L4 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.784); catalogued as rs750578429; called by muse, mutect2, varscan2
- USP6 | c.674G>A p.S225N | Missense Mutation (SNP) | VAF 56/307 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.213); catalogued as rs1349174398, COSV51494644; called by muse, mutect2, varscan2
- USP8 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 77/320 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as rs771430115, COSV56162523; called by muse, mutect2, varscan2
- ZC3HAV1 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 56/468 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV54299403; called by muse, mutect2, varscan2
- ZDBF2 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 123/381 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as rs866727544, COSV65628505; called by muse, mutect2, varscan2
- ZFPM1 | c.2321G>A p.G774E | Missense Mutation (SNP) | VAF 60/294 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.599); catalogued as rs1215157308; called by muse, mutect2, varscan2
- ZNF292 | c.3727A>G p.M1243V | Missense Mutation (SNP) | VAF 25/366 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs1168120151; called by muse, mutect2
- ZNF469 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 76/343 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1367682769; called by muse, mutect2, varscan2
- ABI3 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 46/492 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- AC093827.5 | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 60/333 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ACKR1 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 32/478 reads (7%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRV1 | c.15955G>A p.D5319N | Missense Mutation (SNP) | VAF 23/440 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2
- AMBRA1 | c.3841G>T p.G1281C (on ENST00000458649 / NM_001367468.1; = p.G1191C on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 111/422 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ARR3 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASAH2 | c.1187G>A p.S396N | Missense Mutation (SNP) | VAF 97/333 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- ATP10B | c.2683G>A p.E895K | Missense Mutation (SNP) | VAF 87/362 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- ATP2A3 | c.1879G>A p.D627N | Missense Mutation (SNP) | VAF 159/600 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP4A | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 111/430 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ATP6V1H | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 72/338 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- C19orf38 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 87/462 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- C3orf62 | c.358G>C p.V120L | Missense Mutation (SNP) | VAF 39/460 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.127); called by muse, mutect2
- CAB39 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 122/396 reads (31%) | called by muse, mutect2, varscan2
- CACNA1C | c.4428G>A p.M1476I | Missense Mutation (SNP) | VAF 68/297 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- CCDC150 | c.2591C>T p.S864L | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCDC177 | c.818A>T p.N273I | Missense Mutation (SNP) | VAF 43/669 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.363); called by muse, mutect2
- CD163 | c.1718T>A p.V573D | Missense Mutation (SNP) | VAF 28/639 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- CD8B2 | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- CDH4 | c.2636C>T p.S879F | Missense Mutation (SNP) | VAF 151/640 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEACAM19 | c.670A>C p.T224P | Missense Mutation (SNP) | VAF 32/470 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.548); called by muse, mutect2
- CEACAM7 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- CLIC3 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 120/382 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- COL11A1 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 49/349 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CR1L | c.1532G>A p.G511E | Missense Mutation (SNP) | VAF 70/404 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CST2 | c.341A>G p.K114R | Missense Mutation (SNP) | VAF 120/426 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CYP3A5 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- DNAH11 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 108/375 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- EFCAB5 | c.1673C>T p.S558L | Missense Mutation (SNP) | VAF 78/469 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2
- EGLN1 | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 52/311 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, varscan2
- EML6 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 65/244 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EP400 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 26/564 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ERVV-1 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 58/467 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FBXL12 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 91/459 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FCRL5 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 85/467 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- FREM2 | c.7979G>C p.G2660A | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.059); called by muse, mutect2
- GPHB5 | c.234A>C p.E78D | Missense Mutation (SNP) | VAF 58/351 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- GPR33 | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 112/412 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- GTPBP6 | c.1120C>T p.H374Y | Missense Mutation (SNP) | VAF 74/445 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.118); called by muse, varscan2
- HAPLN1 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 72/273 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HEATR4 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 137/471 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HEATR9 | c.1238A>G p.N413S | Missense Mutation (SNP) | VAF 89/422 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HSPG2 | c.9457C>T p.P3153S | Missense Mutation (SNP) | VAF 53/443 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- HTR5A | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 130/465 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IFIT5 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2
- IGLV5-45 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 110/341 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- KDR | c.1410C>T p.P470= | Splice Region (SNP) | VAF 56/280 reads (20%) | called by muse, mutect2, varscan2
- KLKB1 | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 35/358 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- KMT2A | c.10594G>A p.G3532S | Missense Mutation (SNP) | VAF 47/373 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KSR2 | c.2275G>A p.D759N | Missense Mutation (SNP) | VAF 25/262 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); called by muse, mutect2
- LAIR1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 218/744 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LCT | c.563G>A p.R188K | Missense Mutation (SNP) | VAF 109/399 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LGR6 | c.2125G>A p.G709R (on ENST00000367278 / NM_001017403.1; = p.G657R on NM_021636.3) | Missense Mutation (SNP) | VAF 148/597 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- LRCOL1 | c.214T>C p.C72R | Missense Mutation (SNP) | VAF 28/392 reads (7%) | PolyPhen probably damaging (0.996); called by muse, mutect2
- MAGEC3 | c.898A>G p.N300D | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- MAML3 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 75/429 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MAML3 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 74/426 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- MARK2 | c.1559C>T p.A520V (on ENST00000402010 / NM_001039469.2; = p.A486V on NM_017490.4) | Missense Mutation (SNP) | VAF 100/455 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAST1 | c.901C>T p.H301Y | Missense Mutation (SNP) | VAF 58/406 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MCTP2 | c.1640C>T p.T547I | Missense Mutation (SNP) | VAF 93/296 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MECOM | c.1793C>A p.T598K (on ENST00000468789 / NM_001105078.4; = p.T786K on NM_004991.4) | Missense Mutation (SNP) | VAF 60/353 reads (17%) | SIFT tolerated (0.96); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- MGAT4C | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 28/432 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- MNDA | c.56A>T p.D19V | Missense Mutation (SNP) | VAF 39/293 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- MRGPRF | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 78/489 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MTUS2 | c.1983del p.L662Wfs*28 | Frame Shift Del (DEL) | VAF 58/632 reads (9%) | called by mutect2, pindel
- MTX1 | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 122/683 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- MYO9A | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NHSL1 | c.2051C>T p.S684F | Missense Mutation (SNP) | VAF 34/446 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NOA1 | c.1961C>T p.T654I | Missense Mutation (SNP) | VAF 102/478 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- NPY5R | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 61/324 reads (19%) | called by muse, mutect2, varscan2
- NRG1 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 107/392 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- NUP210 | c.4792G>A p.E1598K | Missense Mutation (SNP) | VAF 83/395 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- OR10AC1 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 88/284 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR10W1 | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 92/395 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR56B1 | c.597T>G p.D199E | Missense Mutation (SNP) | VAF 37/500 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); called by muse, mutect2
- OR6K3 | c.434C>T p.P145L (on ENST00000368146; = p.P129L on NM_001005327.2) | Missense Mutation (SNP) | VAF 86/438 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- OR8H2 | c.745A>G p.T249A | Missense Mutation (SNP) | VAF 21/293 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.327); called by muse, mutect2
- OTOA | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 62/256 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PALLD | c.2371G>A p.G791R (on ENST00000505667 / NM_001166108.2; = p.G774R on NM_016081.4) | Missense Mutation (SNP) | VAF 77/456 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PHTF2 | c.1853C>T p.S618F (on ENST00000248550 / NM_001366089.1; = p.S580F on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PKN3 | c.992T>A p.L331Q | Missense Mutation (SNP) | VAF 112/357 reads (31%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- PNMT | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 87/480 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1595A>G p.N532S | Missense Mutation (SNP) | VAF 124/462 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP1R12C | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 117/510 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- PPP1R12C | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 107/476 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.145); called by muse, varscan2
- PRKCI | c.1734A>T p.E578D | Missense Mutation (SNP) | VAF 56/306 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RHOT1 | c.1357C>T p.H453Y | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- RICTOR | c.4358A>G p.H1453R | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, mutect2
- RNF112 | c.1795G>A p.G599S | Missense Mutation (SNP) | VAF 137/506 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- RNF157 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 123/486 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- RNF213 | c.5737C>T p.H1913Y | Missense Mutation (SNP) | VAF 94/437 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SAMD3 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 29/286 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SEPHS2 | c.1238C>T p.T413M | Missense Mutation (SNP) | VAF 76/377 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.219); called by muse, varscan2
- SHC1 | c.1526T>G p.L509R (on ENST00000368445 / NM_183001.5; = p.L400R on NM_003029.5) | Missense Mutation (SNP) | VAF 87/409 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHCBP1L | c.929A>T p.Y310F | Missense Mutation (SNP) | VAF 19/273 reads (7%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.98); called by muse, mutect2
- SLC25A52 | c.682G>A p.G228R (on ENST00000672005; = p.G218R on NM_001034172.4) | Missense Mutation (SNP) | VAF 126/482 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC35G1 | c.550C>A p.P184T (on ENST00000427197 / NM_001134658.3; = p.P183T on NM_153226.4) | Missense Mutation (SNP) | VAF 115/330 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- SMG6 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 133/495 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNRNP35 | c.394_396del p.L132del | In Frame Del (DEL) | VAF 138/512 reads (27%) | called by mutect2, pindel*
- SPEN | c.5306C>T p.A1769V | Missense Mutation (SNP) | VAF 59/409 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SPTY2D1 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 71/387 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- STAB2 | c.2969G>A p.G990D | Missense Mutation (SNP) | VAF 71/227 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- STT3B | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 61/359 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE2 | c.1130T>A p.I377N | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- SYT6 | c.563T>C p.V188A (on ENST00000610222 / NM_001366225.1; = p.V103A on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/319 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SYT7 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 65/379 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- THSD4 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 36/443 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- TNS4 | c.1067A>T p.E356V | Missense Mutation (SNP) | VAF 128/484 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- TTN | c.7738A>T p.I2580F (on ENST00000591111; = p.I2534F on NM_003319.4) | Missense Mutation (SNP) | VAF 32/394 reads (8%) | PolyPhen benign (0.387); called by muse, mutect2
- TUBA3D | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 111/421 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VWA5B1 | c.2650A>G p.S884G | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2
- YIF1A | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 131/458 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- YWHAE | c.665A>T p.Q222L | Missense Mutation (SNP) | VAF 107/376 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- ZDHHC8 | c.555C>T p.I185= | Splice Region (SNP) | VAF 7/151 reads (5%) | called by muse, mutect2
- ZNF354B | c.1489A>T p.N497Y | Missense Mutation (SNP) | VAF 42/424 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2
- ZNF443 | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 78/466 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.942); called by muse, mutect2
- ZNF592 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 123/498 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF777 | c.2475del p.R826Gfs*119 | Frame Shift Del (DEL) | VAF 59/291 reads (20%) | called by pindel, varscan2
- ZNRF3 | c.2443C>T p.P815S (on ENST00000544604 / NM_001206998.2; = p.P715S on NM_032173.3) | Missense Mutation (SNP) | VAF 120/426 reads (28%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ABCA3 | c.2286G>A p.L762= | Silent (SNP) | VAF 119/465 reads (26%) | catalogued as rs745439512; called by muse, mutect2, varscan2
- ABHD15 | c.984C>T p.F328= | Silent (SNP) | VAF 117/566 reads (21%) | catalogued as rs776555358; called by muse, mutect2, varscan2
- ACTRT2 | c.384C>T p.F128= | Silent (SNP) | VAF 61/470 reads (13%) | catalogued as rs137995220, COSV65759325; called by muse, mutect2, varscan2
- ADGRE1 | c.198T>C p.N66= | Silent (SNP) | VAF 71/393 reads (18%) | catalogued as COSV51676316; called by muse, mutect2, varscan2
- ADGRF3 | c.717C>A p.L239= | Silent (SNP) | VAF 96/297 reads (32%) | called by muse, mutect2, varscan2
- ADRA1A | c.1374C>T p.S458= | Silent (SNP) | VAF 103/419 reads (25%) | called by muse, mutect2, varscan2
- AKAP9 | c.7608C>T p.D2536= (on ENST00000359028; = p.D2512= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/340 reads (9%) | called by muse, mutect2
- AP3B1 | c.289T>C p.L97= | Silent (SNP) | VAF 18/252 reads (7%) | called by muse, mutect2
- ARFGEF2 | c.1308C>T p.L436= | Silent (SNP) | VAF 156/575 reads (27%) | catalogued as COSV64210105; called by muse, mutect2, varscan2
- ARHGEF28 | c.546C>T p.F182= | Silent (SNP) | VAF 82/334 reads (25%) | catalogued as rs373039768; called by muse, mutect2, varscan2
- ATP8A1 | c.2916G>A p.G972= | Silent (SNP) | VAF 113/359 reads (31%) | catalogued as rs749111379; called by muse, mutect2, varscan2
- C11orf42 | c.366G>A p.K122= | Silent (SNP) | VAF 99/473 reads (21%) | catalogued as COSV56412883; called by muse, mutect2, varscan2
- CAMTA1 | c.2205C>T p.I735= | Silent (SNP) | VAF 109/433 reads (25%) | catalogued as rs780428157, COSV100352693; called by muse, mutect2, varscan2
- CDH11 | c.1890C>T p.L630= | Silent (SNP) | VAF 54/268 reads (20%) | called by muse, mutect2, varscan2
- CENPB | c.277C>T p.L93= | Silent (SNP) | VAF 182/569 reads (32%) | catalogued as rs1295480445; called by muse, mutect2, varscan2
- CHST9 | c.1104G>A p.G368= | Silent (SNP) | VAF 90/358 reads (25%) | catalogued as COSV52429061; called by muse, mutect2, varscan2
- CLCN7 | c.498C>T p.F166= | Silent (SNP) | VAF 40/219 reads (18%) | called by muse, mutect2, varscan2
- CLEC4F | c.951C>T p.I317= | Silent (SNP) | VAF 123/371 reads (33%) | called by muse, mutect2, varscan2
- CLVS1 | c.378C>T p.F126= | Silent (SNP) | VAF 126/507 reads (25%) | catalogued as rs760117672, COSV100370874; called by muse, mutect2, varscan2
- COL4A4 | c.2217C>T p.S739= | Silent (SNP) | VAF 113/322 reads (35%) | called by muse, mutect2, varscan2
- CPEB4 | c.585C>T p.V195= | Silent (SNP) | VAF 123/427 reads (29%) | catalogued as COSV99436640; called by muse, mutect2, varscan2
- CRTAM | c.141C>T p.S47= | Silent (SNP) | VAF 91/375 reads (24%) | called by muse, mutect2, varscan2
- CRX | c.138C>T p.F46= | Silent (SNP) | VAF 77/430 reads (18%) | catalogued as rs199607129; called by muse, mutect2, varscan2
- CYP4F22 | c.975C>T p.I325= | Silent (SNP) | VAF 95/403 reads (24%) | called by muse, mutect2, varscan2
- DENND1A | c.2148G>A p.P716= | Silent (SNP) | VAF 62/481 reads (13%) | catalogued as rs373221297; called by muse, mutect2, varscan2
- DENND6B | c.1428C>T p.I476= | Silent (SNP) | VAF 106/369 reads (29%) | called by muse, mutect2, varscan2
- DLG3 | c.1485C>T p.S495= (on ENST00000374360 / NM_021120.4; = p.S158= on NM_020730.3) | Silent (SNP) | VAF 81/165 reads (49%) | catalogued as rs765338624; called by muse, mutect2, varscan2
- DNAH17 | c.5628G>A p.Q1876= | Silent (SNP) | VAF 19/268 reads (7%) | catalogued as rs1341231651; called by muse, mutect2
- DNAJC1 | c.1236C>T p.T412= | Silent (SNP) | VAF 98/369 reads (27%) | called by muse, mutect2, varscan2
- DOCK4 | c.5889C>A p.V1963= | Silent (SNP) | VAF 92/393 reads (23%) | called by muse, mutect2, varscan2
- DSG4 | c.1386G>A p.G462= | Silent (SNP) | VAF 38/237 reads (16%) | catalogued as rs1466140755, COSV57389517; called by muse, mutect2, varscan2
- EFCAB5 | c.1671G>T p.G557= | Silent (SNP) | VAF 82/472 reads (17%) | called by muse, mutect2
- EGLN1 | c.327G>A p.K109= | Silent (SNP) | VAF 60/320 reads (19%) | catalogued as COSV64147919; called by muse, mutect2, varscan2
- FSHR | c.1123C>T p.L375= | Silent (SNP) | VAF 111/390 reads (28%) | called by muse, mutect2, varscan2
- GALNT18 | c.705G>A p.R235= | Silent (SNP) | VAF 99/452 reads (22%) | catalogued as COSV99924936; called by muse, mutect2, varscan2
- GNAT3 | c.567C>T p.F189= | Silent (SNP) | VAF 53/199 reads (27%) | catalogued as COSV101242409; called by muse, mutect2, varscan2
- GPR108 | c.228G>A p.E76= | Silent (SNP) | VAF 81/261 reads (31%) | catalogued as rs1037456090; called by muse, mutect2, varscan2
- GRIA1 | c.867C>T p.T289= | Silent (SNP) | VAF 17/253 reads (7%) | called by muse, mutect2
- GRIN2B | c.3936G>A p.K1312= | Silent (SNP) | VAF 45/646 reads (7%) | called by muse, mutect2
- GRM6 | c.249C>T p.P83= | Silent (SNP) | VAF 93/407 reads (23%) | catalogued as rs752617366, COSV51447874; called by muse, mutect2, varscan2
- GSDME | c.1389G>A p.K463= | Silent (SNP) | VAF 62/404 reads (15%) | catalogued as COSV56040949; called by muse, mutect2, varscan2
- GUCY2F | c.1638C>T p.L546= | Silent (SNP) | VAF 117/218 reads (54%) | catalogued as COSV54301752, COSV54304783; called by muse, mutect2, varscan2
- HMGCLL1 | c.739C>T p.L247= | Silent (SNP) | VAF 76/353 reads (22%) | catalogued as rs201330884; called by muse, mutect2, varscan2
- IL9R | c.42G>A p.E14= | Silent (SNP) | VAF 92/619 reads (15%) | called by muse, varscan2
- IPO9 | c.627C>T p.S209= | Silent (SNP) | VAF 59/279 reads (21%) | called by muse, mutect2, varscan2
- ITGA5 | c.588C>T p.F196= | Silent (SNP) | VAF 81/291 reads (28%) | called by muse, mutect2, varscan2
- KCNQ3 | c.2514G>A p.T838= | Silent (SNP) | VAF 104/685 reads (15%) | catalogued as rs568466967, COSV66470523; called by muse, mutect2, varscan2
- KIR3DL2 | c.666G>A p.E222= | Silent (SNP) | VAF 65/261 reads (25%) | catalogued as rs764462198; called by muse, mutect2, varscan2
- KMT2A | c.10593G>A p.P3531= | Silent (SNP) | VAF 47/373 reads (13%) | catalogued as rs781809083; called by muse, mutect2, varscan2
- KRT3 | c.1716C>T p.I572= | Silent (SNP) | VAF 185/605 reads (31%) | called by muse, mutect2, varscan2
- KRTAP9-1 | c.555C>T p.C185= | Silent (SNP) | VAF 26/368 reads (7%) | called by muse, mutect2
- LARP1 | c.1926G>A p.K642= (on ENST00000518297 / NM_033551.3; = p.K565= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 90/375 reads (24%) | called by muse, mutect2, varscan2
- LEPR | c.2220C>T p.I740= | Silent (SNP) | VAF 17/150 reads (11%) | catalogued as rs757501135, COSV60750793; called by muse, mutect2, varscan2
- LPA | c.5169G>A p.G1723= | Silent (SNP) | VAF 33/293 reads (11%) | catalogued as rs768072721, COSV60297366; called by muse, mutect2, varscan2
- LRRC30 | c.75G>A p.Q25= | Silent (SNP) | VAF 45/515 reads (9%) | called by muse, mutect2
- LRRC4B | c.1851C>T p.I617= | Silent (SNP) | VAF 170/628 reads (27%) | catalogued as COSV65350349; called by muse, mutect2, varscan2
- MXRA5 | c.1509G>A p.V503= | Silent (SNP) | VAF 46/337 reads (14%) | catalogued as rs769179179; called by muse, mutect2, varscan2
- MYO7A | c.2505C>T p.H835= | Silent (SNP) | VAF 91/564 reads (16%) | catalogued as rs1366672672; called by muse, mutect2, varscan2
- NCR3 | c.141A>G p.R47= | Silent (SNP) | VAF 127/654 reads (19%) | called by muse, mutect2, varscan2
- NIBAN1 | c.1053G>A p.L351= | Silent (SNP) | VAF 90/317 reads (28%) | catalogued as COSV62284294; called by muse, mutect2, varscan2
- NOA1 | c.1962C>T p.T654= | Silent (SNP) | VAF 102/476 reads (21%) | catalogued as COSV51735729; called by muse, mutect2, varscan2
- NTN1 | c.1167C>T p.R389= | Silent (SNP) | VAF 36/436 reads (8%) | catalogued as rs368406936; called by muse, mutect2
- ODF2 | c.1023C>T p.S341= (on ENST00000434106 / NM_153433.2; = p.S317= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 85/246 reads (35%) | catalogued as rs1007603611; called by muse, mutect2, varscan2
- OR11L1 | c.819C>T p.I273= | Silent (SNP) | VAF 63/292 reads (22%) | catalogued as COSV100869410, COSV63313737; called by muse, mutect2, varscan2
- OR2L3 | c.291G>A p.G97= | Silent (SNP) | VAF 84/380 reads (22%) | catalogued as COSV63455181; called by muse, varscan2
- OR4K1 | c.918G>A p.V306= | Silent (SNP) | VAF 26/310 reads (8%) | catalogued as rs1416963093, COSV99579343; called by muse, mutect2
- OR4N5 | c.489C>T p.I163= | Silent (SNP) | VAF 38/508 reads (7%) | called by muse, mutect2
- OR51F1 | c.900C>T p.I300= | Silent (SNP) | VAF 43/347 reads (12%) | catalogued as rs748134868, COSV58579266; called by muse, mutect2, varscan2
- PARP6 | c.558C>T p.F186= | Silent (SNP) | VAF 63/244 reads (26%) | called by muse, mutect2, varscan2
- PCDH17 | c.3159C>T p.S1053= | Silent (SNP) | VAF 234/566 reads (41%) | called by muse, mutect2, varscan2
- PCDH17 | c.3235C>T p.L1079= | Silent (SNP) | VAF 134/553 reads (24%) | catalogued as COSV100931544; called by muse, mutect2, varscan2
- PCDHGB7 | c.717C>T p.P239= | Silent (SNP) | VAF 122/395 reads (31%) | called by muse, mutect2, varscan2
- PCNX2 | c.4911G>A p.G1637= | Silent (SNP) | VAF 84/383 reads (22%) | called by muse, mutect2, varscan2
- PHLDB2 | c.1290G>A p.R430= | Silent (SNP) | VAF 19/427 reads (4%) | called by muse, mutect2
- PLCE1 | c.4539C>T p.F1513= | Silent (SNP) | VAF 56/191 reads (29%) | catalogued as COSV99592834; called by muse, mutect2, varscan2
- PLEKHA5 | c.3231T>G p.V1077= | Silent (SNP) | VAF 94/537 reads (18%) | catalogued as COSV54703773; called by muse, mutect2, varscan2
- PLEKHA6 | c.3006C>T p.A1002= | Silent (SNP) | VAF 85/336 reads (25%) | called by muse, mutect2, varscan2
- PLXNB3 | c.4026C>T p.F1342= | Silent (SNP) | VAF 200/370 reads (54%) | called by muse, mutect2, varscan2
- POTEJ | c.2613C>T p.I871= | Silent (SNP) | VAF 126/518 reads (24%) | catalogued as rs764884437; called by muse, mutect2, varscan2
- PRM1 | c.36G>A p.R12= | Silent (SNP) | VAF 66/306 reads (22%) | catalogued as COSV54113308; called by muse, mutect2, varscan2
- PRR23D1 | c.177G>A p.L59= | Silent (SNP) | VAF 75/512 reads (15%) | called by muse, mutect2, varscan2
- PRSS1 | c.552C>T p.F184= | Silent (SNP) | VAF 46/322 reads (14%) | catalogued as rs767583768, COSV61197470; called by muse, varscan2
- RBM25 | c.474C>T p.L158= | Silent (SNP) | VAF 65/426 reads (15%) | catalogued as rs1281266093, COSV56199438; called by muse, mutect2, varscan2
- RTN4 | c.1506C>T p.A502= | Silent (SNP) | VAF 82/285 reads (29%) | called by muse, mutect2, varscan2
- SASH1 | c.2808T>C p.P936= | Silent (SNP) | VAF 25/427 reads (6%) | called by muse, mutect2
- SCN2A | c.4884C>T p.I1628= | Silent (SNP) | VAF 141/456 reads (31%) | called by muse, mutect2, varscan2
- SEZ6 | c.807G>A p.L269= | Silent (SNP) | VAF 81/501 reads (16%) | catalogued as rs749085922, COSV100253091; called by muse, mutect2, varscan2
- SLC23A3 | c.1392C>T p.A464= (on ENST00000409878 / NM_001144889.2; = p.A347= on NM_144712.5) | Silent (SNP) | VAF 18/454 reads (4%) | called by muse, mutect2
- SLC2A11 | c.1095C>T p.F365= (on ENST00000345044 / NM_001024938.4; = p.F372= on NM_030807.5) | Silent (SNP) | VAF 173/585 reads (30%) | catalogued as rs1234808196; called by muse, mutect2, varscan2
- SLC4A11 | c.754C>T p.L252= | Silent (SNP) | VAF 121/385 reads (31%) | called by muse, mutect2, varscan2
- SLC8A3 | c.2382C>T p.F794= (on ENST00000381269 / NM_183002.3; = p.F792= on NM_033262.4) | Silent (SNP) | VAF 146/451 reads (32%) | catalogued as rs368263429; called by muse, mutect2, varscan2
- SLC9A2 | c.918C>T p.I306= | Silent (SNP) | VAF 112/339 reads (33%) | catalogued as COSV52134308; called by muse, mutect2, varscan2
- SMARCAL1 | c.2313C>T p.F771= | Silent (SNP) | VAF 129/469 reads (28%) | called by muse, mutect2, varscan2
- SOCS7 | c.1893G>A p.A631= | Silent (SNP) | VAF 90/383 reads (23%) | catalogued as rs138060923; called by muse, mutect2, varscan2
- SPATA31D4 | c.2346C>T p.L782= | Silent (SNP) | VAF 116/724 reads (16%) | called by muse, mutect2, varscan2
- SPEN | c.5307C>T p.A1769= | Silent (SNP) | VAF 60/416 reads (14%) | called by muse, mutect2, varscan2
- SPTA1 | c.3603G>A p.K1201= | Silent (SNP) | VAF 81/339 reads (24%) | called by muse, mutect2, varscan2
- STYXL2 | c.2832G>A p.T944= | Silent (SNP) | VAF 79/356 reads (22%) | catalogued as rs149238405; called by muse, mutect2, varscan2
- SYNE1 | c.11515C>T p.L3839= (on ENST00000367255 / NM_182961.4; = p.L3824= on NM_033071.3) | Silent (SNP) | VAF 60/272 reads (22%) | called by muse, mutect2, varscan2
- SYNPO | c.1128C>T p.S376= (on ENST00000394243 / NM_001166208.2; = p.S132= on NM_007286.6) | Silent (SNP) | VAF 118/425 reads (28%) | called by muse, mutect2, varscan2
- TAP2 | c.1860C>T p.A620= | Silent (SNP) | VAF 118/528 reads (22%) | called by muse, mutect2
- TAPT1 | c.352C>T p.L118= | Silent (SNP) | VAF 55/278 reads (20%) | catalogued as rs1410274316; called by muse, mutect2, varscan2
- TAS2R46 | c.363A>G p.L121= | Silent (SNP) | VAF 200/617 reads (32%) | called by muse, mutect2, varscan2
- TENM3 | c.7953G>A p.T2651= | Silent (SNP) | VAF 29/337 reads (9%) | catalogued as rs767130832; called by muse, mutect2
- TEX13D | c.1641G>A p.G547= | Silent (SNP) | VAF 95/256 reads (37%) | called by muse, varscan2
- TJP1 | c.5043C>T p.I1681= | Silent (SNP) | VAF 38/385 reads (10%) | called by muse, mutect2
- TMC7 | c.117C>T p.F39= | Silent (SNP) | VAF 66/317 reads (21%) | catalogued as COSV58582004, COSV58587883; called by muse, mutect2, varscan2
- TOGARAM2 | c.1458G>A p.S486= | Silent (SNP) | VAF 118/372 reads (32%) | catalogued as rs776145601, COSV65423119; called by muse, mutect2, varscan2
- TRAF5 | c.1071C>T p.T357= | Silent (SNP) | VAF 58/236 reads (25%) | called by muse, mutect2, varscan2
- TRANK1 | c.7131G>A p.R2377= | Silent (SNP) | VAF 73/397 reads (18%) | called by muse, mutect2, varscan2
- TRIM24 | c.2937C>T p.F979= (on ENST00000343526 / NM_015905.3; = p.F945= on NM_003852.4) | Silent (SNP) | VAF 68/225 reads (30%) | called by muse, mutect2, varscan2
- VPS37D | c.729C>T p.P243= | Silent (SNP) | VAF 16/183 reads (9%) | catalogued as rs1035501695; called by muse, mutect2
- VPS53 | c.1152C>T p.P384= (on ENST00000571805 / NM_001366253.2; = p.P355= on NM_018289.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/379 reads (21%) | catalogued as rs1241098090; called by muse, mutect2, varscan2
- ZG16B | c.150C>T p.T50= | Silent (SNP) | VAF 124/549 reads (23%) | called by muse, mutect2, varscan2
- ZNF460 | c.510C>T p.S170= | Silent (SNP) | VAF 74/383 reads (19%) | called by muse, mutect2, varscan2
- ZNF511 | c.700C>T p.L234= | Silent (SNP) | VAF 74/312 reads (24%) | catalogued as rs775734845; called by muse, mutect2, varscan2
- ZNF646 | c.3867C>T p.T1289= | Silent (SNP) | VAF 106/537 reads (20%) | called by muse, mutect2, varscan2
- AANAT | c.-49G>A | 5'UTR (SNP) | VAF 81/382 reads (21%) | called by muse, mutect2, varscan2
- ACAN | c.2026+17C>T | Intron (SNP) | VAF 48/385 reads (12%) | catalogued as rs367736498; called by muse, mutect2, varscan2
- ACP2 | c.639+66C>T | Intron (SNP) | VAF 95/435 reads (22%) | catalogued as rs1189501638; called by muse, mutect2, varscan2
- CYLD | c.-36C>T | 5'UTR (SNP) | VAF 78/357 reads (22%) | catalogued as rs1183633894; called by muse, mutect2, varscan2
- GALNTL6 | c.139-177197C>T | Intron (SNP) | VAF 41/251 reads (16%) | catalogued as COSV72492980; called by muse, mutect2, varscan2
- KCNK4 | c.*10C>T | 3'UTR (SNP) | VAF 75/559 reads (13%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+403G>A | Intron (SNP) | VAF 42/279 reads (15%) | called by muse, mutect2, varscan2
- RICTOR | c.4136+288C>T | Intron (SNP) | VAF 17/248 reads (7%) | catalogued as rs774111455, COSV57126383; called by muse, mutect2
